Somatic mutation profile of tumor specimen TCGA-B9-A44B-01A (aliquot TCGA-B9-A44B-01A-11D-A25F-10) from TCGA case TCGA-B9-A44B, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 70.5 years (25,763 days).
Specimen TCGA-B9-A44B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84c6f630-5f6c-47a0-bd3e-f6029dfe74c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-A44B-10A (Blood Derived Normal), aliquot TCGA-B9-A44B-10A-01D-A25F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1318dab3-02b7-485c-baa9-85011a717a34

The open-access MAF lists 164 somatic variants for this specimen: 121 protein-altering or splice-affecting, 27 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 27, Frame Shift Del 17, 3'UTR 7, In Frame Del 5, Frame Shift Ins 5, Intron 4, 5'UTR 3, Nonsense Mutation 3, RNA 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC4 | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs766357126, COSV65312222; called by muse, mutect2, varscan2
- ACIN1 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 100/214 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV52975813; called by muse, mutect2, varscan2
- ADCK2 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV50781264; called by muse, mutect2, varscan2
- ADGRE5 | c.1835G>T p.C612F (on ENST00000242786 / NM_078481.4; = p.C519F on NM_001784.5) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54391411; called by mutect2, varscan2
- ALK | c.4008G>T p.Q1336H | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66566496; called by muse, mutect2, varscan2
- ATXN7L2 | c.305G>C p.R102T | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV63992271; called by muse, mutect2, varscan2
- AXDND1 | c.2261A>C p.K754T | Missense Mutation (SNP) | VAF 47/278 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV62642153; called by muse, mutect2, varscan2
- BCAS4 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 100/229 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); catalogued as COSV52811159; called by muse, mutect2, varscan2
- BRCA2 | c.3791A>G p.K1264R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.085); catalogued as COSV66453020; called by mutect2, varscan2
- CACNA2D4 | c.3379T>C p.C1127R | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as COSV54949508; called by muse, mutect2, varscan2
- CARD14 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs774755867, COSV60123206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAVIN1 | c.519A>T p.K173N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as COSV63811788; called by muse, mutect2
- CCDC121 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53114401; called by muse, mutect2, varscan2
- CDH9 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.047); catalogued as rs150604531, COSV50276932, COSV99141765; called by muse, mutect2, varscan2
- CDIN1 | c.626T>A p.I209K (on ENST00000437989; = p.I111K on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV57711077; called by muse, varscan2
- CECR2 | c.4165G>A p.A1389T (on ENST00000342247 / NM_001290047.2; = p.A1205T on NM_001290046.1) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1446883743, COSV52840275, COSV52850464; called by muse, mutect2, varscan2
- CELF3 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51883203; called by muse, mutect2, varscan2
- COLCA2 | c.323C>G p.S108W | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67695186, COSV67695274; called by muse, mutect2
- DAPK2 | c.939G>C p.R313S | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV56045292; called by muse, mutect2, varscan2
- DCHS1 | c.2711C>A p.P904Q | Missense Mutation (SNP) | VAF 96/210 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55034789; called by muse, mutect2, varscan2
- DNALI1 | c.757_759del p.K253del (on ENST00000296218; = p.K231del on NM_003462.5) | In Frame Del (DEL) | VAF 45/92 reads (49%) | catalogued as rs757201027; called by pindel, varscan2
- DOCK9 | c.5963A>G p.N1988S (on ENST00000376460 / NM_001366676.2; = p.N1989S on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs757371392, COSV59627474; called by muse, mutect2
- DSG3 | c.262T>G p.S88A | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV57125970; called by muse, mutect2, varscan2
- DSP | c.712del p.I238Sfs*22 | Frame Shift Del (DEL) | VAF 36/90 reads (40%) | catalogued as COSV65791761; called by mutect2, varscan2
- EEF1D | c.813G>C p.Q271H | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52784592; called by muse, mutect2, varscan2
- EFCAB5 | c.531A>T p.K177N | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); catalogued as COSV57929295; called by muse, mutect2, varscan2
- EIF4A2 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV56216759; called by muse, mutect2, varscan2
- FBXO3 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55766048; called by muse, mutect2, varscan2
- FUT11 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as rs1235067667, COSV59541587; called by muse, mutect2, varscan2
- GDNF | c.-26-1G>T | Splice Site (SNP) | VAF 17/43 reads (40%) | catalogued as rs13169425, COSV58479281; called by muse, mutect2, varscan2
- HACE1 | c.164T>A p.F55Y | Missense Mutation (SNP) | VAF 55/94 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53501969; called by muse, mutect2, varscan2
- HERPUD2 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.78); catalogued as COSV60944930; called by muse, mutect2, varscan2
- HS1BP3 | c.1069G>C p.A357P | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58312879; called by muse, mutect2, varscan2
- IGF2R | c.586T>C p.Y196H | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV63628677; called by muse, mutect2, varscan2
- ITPRID1 | c.1734C>A p.D578E | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.107); catalogued as COSV60073729; called by muse, mutect2, varscan2
- KAT6B | c.3050G>C p.C1017S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV54746068; called by muse, mutect2, varscan2
- KCNAB2 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs773529675, COSV51236524; called by muse, mutect2
- KIF21A | c.2668C>G p.Q890E (on ENST00000361418 / NM_001378440.1; = p.Q877E on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV62770858; called by muse, mutect2, varscan2
- KLC4 | c.1754T>C p.M585T | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV52435387; called by muse, varscan2
- KRT85 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as COSV57736725; called by muse, mutect2, varscan2
- LONP2 | c.1379T>G p.L460R | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53522182; called by muse, mutect2, varscan2
- MAP2K3 | c.723C>A p.N241K (on ENST00000342679 / NM_145109.3; = p.N212K on NM_002756.4) | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.742); catalogued as COSV57566617; called by muse, mutect2
- MATR3 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV63077097; called by muse, mutect2, varscan2
- MBTD1 | c.152T>G p.M51R | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as COSV64503298; called by muse, mutect2, varscan2
- MDC1 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV64524395; called by muse, mutect2
- MDN1 | c.10436C>G p.S3479* | Nonsense Mutation (SNP) | VAF 41/194 reads (21%) | catalogued as COSV65521034; called by muse, mutect2, varscan2
- MED13 | c.4700A>G p.N1567S | Missense Mutation (SNP) | VAF 95/240 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs756773824, COSV67263288; called by muse, mutect2, varscan2
- MINK1 | c.884A>G p.E295G | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV61789918; called by muse, mutect2, varscan2
- MKRN2 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 71/77 reads (92%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV50104915; called by muse, mutect2, varscan2
- MRPL24 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs761140936, COSV61976053; called by muse, mutect2, varscan2
- MSS51 | c.326G>T p.R109I | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV55019161; called by muse, mutect2, varscan2
- MYO10 | c.3923T>G p.V1308G | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57020747; called by muse, mutect2, varscan2
- NAT9 | c.446A>C p.N149T | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52853145; called by muse, mutect2, varscan2
- NEUROD6 | c.444A>T p.E148D | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV51771273; called by muse, mutect2, varscan2
- NEUROD6 | c.443A>T p.E148V | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51771292; called by muse, mutect2, varscan2
- NUS1 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs1052270685, COSV63844126; called by muse, mutect2, varscan2
- NUSAP1 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV52971055; called by muse, mutect2, varscan2
- PARP6 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV53002995; called by muse, mutect2, varscan2
- PBRM1 | c.2669C>A p.A890E | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56273754; called by muse, mutect2, varscan2
- PCLO | c.5003A>G p.K1668R | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as COSV61632330; called by muse, mutect2, varscan2
- PDCD11 | c.5503_5505del p.F1835del | In Frame Del (DEL) | VAF 45/184 reads (24%) | catalogued as rs755018593; called by pindel, varscan2
- PGAP1 | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV61325826; called by muse, mutect2, varscan2
- PHLDB1 | c.2702G>A p.R901K | Missense Mutation (SNP) | VAF 68/84 reads (81%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV61878122; called by muse, mutect2, varscan2
- PKD1L1 | c.7102G>A p.G2368R | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs147316882; called by muse, mutect2, varscan2
- PLK1 | c.169C>A p.R57S | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.822); catalogued as rs757915883, COSV55621841; called by muse, mutect2, varscan2
- POC1A | c.527G>T p.S176I | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV56591299; called by muse, mutect2, varscan2
- POLA1 | c.1328T>A p.I443K | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV66885826; called by muse, mutect2, varscan2
- POMZP3 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 111/383 reads (29%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.655); catalogued as COSV51885542, COSV51886418; called by muse, mutect2, varscan2
- POTEH | c.1499C>A p.T500N | Missense Mutation (SNP) | VAF 111/1041 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV58882397; called by muse, mutect2, varscan2
- PRKAR2B | c.1197T>A p.Y399* | Nonsense Mutation (SNP) | VAF 43/114 reads (38%) | catalogued as COSV55924495; called by muse, mutect2
- PRRC1 | c.395G>C p.G132A | Missense Mutation (SNP) | VAF 79/170 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.052); catalogued as COSV56988980; called by muse, mutect2, varscan2
- PTPRB | c.5220T>A p.D1740E | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54239577; called by muse, mutect2, varscan2
- RDH11 | c.77A>C p.K26T | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.295); catalogued as COSV67282685; called by muse, mutect2, varscan2
- RHBDD2 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 19/378 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs375383259; called by muse, mutect2
- RNF19A | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs865845130, COSV61993036; called by muse, mutect2, varscan2
- RSKR | c.809T>C p.M270T | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV56381904; called by muse, mutect2, varscan2
- SCN2A | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 98/187 reads (52%) | catalogued as rs1553564373, COSV51839548; called by muse, mutect2, varscan2
- SENP8 | c.497A>T p.Y166F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); catalogued as COSV61767920; called by muse, mutect2, varscan2
- SLC25A53 | c.604G>A p.G202S | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV62459073; called by muse, mutect2, varscan2
- SLC44A3 | c.1952T>C p.I651T (on ENST00000271227 / NM_001114106.3; = p.I603T on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/272 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs776111628, COSV54729844; called by muse, mutect2, varscan2
- SNAP91 | c.379T>A p.Y127N | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52121289; called by muse, mutect2, varscan2
- SOBP | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); catalogued as COSV57997924; called by mutect2, varscan2
- SPACA1 | c.773C>A p.P258H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.562); catalogued as COSV52759700; called by muse, mutect2, varscan2
- SPEN | c.5602T>G p.L1868V | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.051); catalogued as COSV65361258; called by muse, mutect2, varscan2
- SYNE2 | c.15404A>G p.Y5135C | Missense Mutation (SNP) | VAF 82/155 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs556819169, COSV59949266; called by muse, mutect2, varscan2
- THPO | c.1148T>G p.I383S (on ENST00000649095 / NM_001290003.1; = p.I243S on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); catalogued as COSV52615623; called by muse, mutect2, varscan2
- TMCC3 | c.1396A>G p.I466V | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.956); catalogued as COSV54153060; called by muse, mutect2, varscan2
- TSPOAP1 | c.5519C>T p.P1840L | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as COSV52107756; called by muse, mutect2
- TTC34 | c.2078C>A p.S693Y | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1051039842; called by muse, mutect2
- WDR20 | c.1162C>A p.L388I | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as COSV54471979; called by muse, mutect2, varscan2
- WFDC8 | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.388); catalogued as COSV51489491; called by muse, mutect2, varscan2
- YIPF3 | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV58304577; called by muse, mutect2, varscan2
- ZDHHC8 | c.715A>T p.N239Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57710046; called by muse, mutect2, varscan2
- ZNF622 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1387858247, COSV58073992; called by muse, mutect2, varscan2
- ARID2 | c.305_306del p.K102Sfs*8 | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | called by mutect2, pindel, varscan2
- C22orf42 | c.184_186del p.Q62del | In Frame Del (DEL) | VAF 54/246 reads (22%) | called by mutect2, pindel, varscan2
- C2CD5 | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by mutect2, varscan2
- CD6 | c.1142_1150del p.V381_I383del | In Frame Del (DEL) | VAF 78/181 reads (43%) | called by mutect2, pindel, varscan2
- CFAP73 | c.732_733del p.K244Nfs*58 | Frame Shift Del (DEL) | VAF 30/77 reads (39%) | called by mutect2, pindel, varscan2
- CHD4 | c.4197+3_4197+6del | Splice Region (DEL) | VAF 15/37 reads (41%) | called by pindel, varscan2
- CTTNBP2NL | c.1305del p.K435Nfs*19 | Frame Shift Del (DEL) | VAF 76/155 reads (49%) | called by mutect2, pindel, varscan2
- EFCAB14 | c.1427_1428del p.F476* | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | called by mutect2, pindel, varscan2
- EPS15L1 | c.221_222del p.Y74Cfs*14 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | called by mutect2, pindel, varscan2
- FANCI | c.123del p.V42Lfs*6 | Frame Shift Del (DEL) | VAF 39/103 reads (38%) | called by mutect2, pindel, varscan2
- FUT10 | c.1010dup p.R338Qfs*6 | Frame Shift Ins (INS) | VAF 105/311 reads (34%) | called by mutect2, pindel, varscan2
- HEPHL1 | c.646_663del p.S216_D221del | In Frame Del (DEL) | VAF 29/80 reads (36%) | called by mutect2, pindel, varscan2
- HNRNPUL2 | c.721del p.E241Rfs*6 | Frame Shift Del (DEL) | VAF 79/163 reads (48%) | called by mutect2, pindel, varscan2
- KCNH3 | c.2631_2632del p.L878Gfs*133 | Frame Shift Del (DEL) | VAF 42/112 reads (38%) | called by pindel, varscan2
- KLC4 | c.1753_1754insCGACAACA p.M585Tfs*4 | Frame Shift Ins (INS) | VAF 38/123 reads (31%) | called by pindel, varscan2
- NPTX1 | c.596del p.V199Afs*7 | Frame Shift Del (DEL) | VAF 45/122 reads (37%) | called by mutect2, pindel, varscan2
- PCLO | c.10863del p.V3622Sfs*15 | Frame Shift Del (DEL) | VAF 37/107 reads (35%) | called by mutect2, pindel, varscan2
- PXN | c.997del p.Q333Sfs*13 (on ENST00000228307 / NM_001080855.3; = p.Q299Sfs*13 on NM_002859.4) | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- RBM33 | c.2120dup p.N707Kfs*4 | Frame Shift Ins (INS) | VAF 56/162 reads (35%) | called by mutect2, pindel, varscan2
- RCAN3 | c.95del p.N32Mfs*8 | Frame Shift Del (DEL) | VAF 108/277 reads (39%) | called by mutect2, pindel, varscan2
- RPSA | c.793+5_793+8del p.X265_splice | Splice Site (DEL) | VAF 16/20 reads (80%) | called by pindel, varscan2
- SETD2 | c.2159dup p.F721Ifs*5 | Frame Shift Ins (INS) | VAF 32/54 reads (59%) | called by mutect2, pindel, varscan2
- SLC17A3 | c.887del p.L296* | Frame Shift Del (DEL) | VAF 37/103 reads (36%) | called by mutect2, pindel, varscan2
- STAB1 | c.6119dup p.C2041Lfs*2 | Frame Shift Ins (INS) | VAF 17/82 reads (21%) | called by mutect2, varscan2
- SUFU | c.69_75del p.P24Sfs*70 | Frame Shift Del (DEL) | VAF 11/13 reads (85%) | called by mutect2, varscan2
- TMPRSS11A | c.1215del p.Y405* | Frame Shift Del (DEL) | VAF 63/141 reads (45%) | called by mutect2, pindel*, varscan2
- ZNF648 | c.228_234del p.E77Rfs*29 | Frame Shift Del (DEL) | VAF 33/151 reads (22%) | called by mutect2, pindel, varscan2
- ABCA7 | c.5448G>T p.G1816= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV54028749; called by muse, mutect2, varscan2
- ACOT9 | c.942C>T p.F314= | Silent (SNP) | VAF 46/62 reads (74%) | catalogued as COSV60537530; called by muse, mutect2, varscan2
- ADGRG6 | c.717C>T p.V239= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV51591157; called by muse, mutect2, varscan2
- ANKIB1 | c.723T>C p.I241= | Silent (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- CATSPER2 | c.132C>T p.I44= | Silent (SNP) | VAF 172/415 reads (41%) | catalogued as COSV58660745, COSV58661444; called by muse, varscan2
- CHD6 | c.651G>T p.T217= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV58556698; called by muse, mutect2, varscan2
- FARP2 | c.2103C>G p.P701= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV50870901; called by muse, mutect2
- GPR152 | c.153G>A p.A51= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs113329646, COSV56886227; called by muse, mutect2, varscan2
- GRID1 | c.1680A>C p.P560= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV60026165, COSV60050897; called by muse, mutect2, varscan2
- GRPEL2 | c.327C>T p.F109= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs1024505337, COSV61387575; called by muse, mutect2, varscan2
- IFI30 | c.549C>T p.R183= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as rs1481273506, COSV69576524; called by muse, mutect2, varscan2
- KCNH6 | c.2790A>G p.A930= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as rs763160143, COSV59003036; called by muse, mutect2, varscan2
- LRP2 | c.8568T>C p.P2856= | Silent (SNP) | VAF 46/137 reads (34%) | catalogued as COSV55551448; called by muse, mutect2, varscan2
- MELK | c.69A>G p.A23= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV53198604; called by muse, mutect2, varscan2
- MFSD12 | c.1179C>T p.L393= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs766443026, COSV61535406; called by muse, mutect2
- MROH5 | c.1497C>T p.T499= | Silent (SNP) | VAF 62/118 reads (53%) | catalogued as COSV71301387; called by muse, mutect2, varscan2
- MYBL2 | c.903C>T p.I301= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV53829449; called by muse, mutect2, varscan2
- OR4F6 | c.720G>T p.L240= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV61026701; called by muse, mutect2, varscan2
- PRPH | c.621C>T p.A207= | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as COSV57678504; called by muse, mutect2
- RGPD3 | c.400C>T p.L134= | Silent (SNP) | VAF 121/308 reads (39%) | catalogued as COSV58740962; called by muse, mutect2, varscan2
- RSPO2 | c.552A>G p.T184= | Silent (SNP) | VAF 112/240 reads (47%) | catalogued as COSV52643422; called by muse, mutect2
- SLMAP | c.153A>G p.L51= | Silent (SNP) | VAF 211/254 reads (83%) | catalogued as rs147270008; called by muse, varscan2
- TCP11 | c.1494A>C p.T498= (on ENST00000512012; = p.T436= on NM_018679.5) | Silent (SNP) | VAF 79/187 reads (42%) | catalogued as COSV55133608; called by muse, mutect2, varscan2
- TP53BP1 | c.657A>G p.E219= | Silent (SNP) | VAF 95/264 reads (36%) | catalogued as COSV55500411; called by muse, mutect2, varscan2
- ZNF281 | c.2019A>G p.Q673= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs754629206, COSV54166936; called by muse, mutect2, varscan2
- ZNF507 | c.2409T>A p.S803= | Silent (SNP) | VAF 97/180 reads (54%) | catalogued as COSV61331048; called by muse, varscan2
- ZNF799 | c.654G>A p.T218= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as rs1238520227, COSV70122117, COSV70122457; called by muse, mutect2
- CFAP74 | c.296+423C>T | Intron (SNP) | VAF 11/28 reads (39%) | catalogued as rs778736733, COSV54565826; called by muse, mutect2, varscan2
- DCAF4L1 | c.*3028G>C | 3'UTR (SNP) | VAF 33/80 reads (41%) | catalogued as COSV100048130; called by muse, mutect2, varscan2
- FAM182A | n.836C>A | RNA (SNP) | VAF 24/132 reads (18%) | catalogued as rs1251053754; called by muse, mutect2, varscan2
- HEXIM1 | c.*316G>C | 3'UTR (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100203460; called by muse, mutect2, varscan2
- IRAK1 | c.*750del | 3'UTR (DEL) | VAF 24/38 reads (63%) | called by mutect2, pindel, varscan2
- LRRN3 | c.*506A>T | 3'UTR (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100069535; called by muse, mutect2, varscan2
- MTHFD1 | c.2719-1535T>C | Intron (SNP) | VAF 22/51 reads (43%) | catalogued as COSV53700024; called by muse, mutect2, varscan2
- NANOS1 | c.*1874C>A | 3'UTR (SNP) | VAF 31/134 reads (23%) | catalogued as COSV100403870; called by muse, mutect2, varscan2
- NECAB3 | c.*13C>G | 3'UTR (SNP) | VAF 16/82 reads (20%) | catalogued as COSV99864678; called by muse, mutect2, varscan2
- ORC4 | c.-10del | 5'UTR (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2
- SNAP25 | c.114+16del | Intron (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- STARD7-AS1 | n.1734C>A | RNA (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- TBX19 | c.604-56T>C | Intron (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- UBE2L6 | c.-10C>G | 5'UTR (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99761853; called by muse, mutect2, varscan2
- ZBTB43 | c.*367T>C | 3'UTR (SNP) | VAF 57/71 reads (80%) | catalogued as rs1466779101, COSV100991344; called by muse, mutect2, varscan2
- ZNF85 | c.-43G>C | 5'UTR (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100059675; called by muse, mutect2, varscan2
